Somatic mutation profile of tumor specimen BA2570D (aliquot aq-BA2570D) from BEATAML1.0 case 2367, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.5 years (16,978 days).
Specimen BA2570D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e72a0305-79a8-4e8c-880b-f61b61f9d906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2203D (Solid Tissue Normal), aliquot aq-BA2203D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b210a2ee-397a-4bf6-a261-8ebdbd4ad5dc

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI4 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as rs1326260314; called by muse, mutect2
- TJP3 | c.2362C>A p.H788N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
